Somatic mutation profile of tumor specimen TCGA-AX-A2H2-01A (aliquot TCGA-AX-A2H2-01A-11D-A17W-09) from TCGA case TCGA-AX-A2H2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 86.3 years (31,524 days).
Specimen TCGA-AX-A2H2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00b8d803-7148-4c02-a1e6-45840276cd7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2H2-11A (Solid Tissue Normal), aliquot TCGA-AX-A2H2-11A-13D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83e8d306-fe44-4a34-90bb-a131010a0751

The open-access MAF lists 208 somatic variants for this specimen: 158 protein-altering or splice-affecting, 44 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 44, Nonsense Mutation 17, Splice Site 4, 5'UTR 2, Frame Shift Del 2, Intron 2, Splice Region 2, RNA 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 19/31 reads (61%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABHD15 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56195049; called by muse, mutect2, varscan2
- AC008397.2 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV53206284, COSV99441114, COSV99442346; called by muse, mutect2
- ACE | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV99326611; called by muse, mutect2, varscan2
- ACVR2A | c.264G>C p.R88S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV54024829, COSV99604167; called by muse, mutect2, varscan2
- ADAM33 | c.2284C>T p.H762Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100597745; called by muse, mutect2, varscan2
- ADAMTS2 | c.3416C>T p.P1139L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99281349; called by muse, mutect2, varscan2
- AHNAK | c.10044G>C p.K3348N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99946287, COSV99947809; called by muse, mutect2, varscan2
- AKNA | c.3017C>A p.A1006E | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as COSV99799911; called by muse, mutect2, varscan2
- AKNA | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV99799916; called by muse, mutect2, varscan2
- AKNAD1 | c.1551C>G p.H517Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV100645391, COSV100645666; called by muse, mutect2, varscan2
- ANAPC7 | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV101484777, COSV71443742; called by muse, mutect2, varscan2
- ANKIB1 | c.3194G>A p.R1065K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV99728631; called by muse, mutect2, varscan2
- ANXA13 | c.743A>C p.D248A | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99146054; called by muse, mutect2, varscan2
- ATAD2B | c.3889G>T p.D1297Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV99477187; called by muse, mutect2, varscan2
- ATG2A | c.3958C>T p.R1320W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs747927573, COSV65965814; called by muse, mutect2, varscan2
- BCAM | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758400698, COSV54305196; called by muse, mutect2, varscan2
- BCL9L | c.2664C>G p.S888R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99418882; called by muse, mutect2, varscan2
- BEST1 | c.222G>C p.Q74H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV100076993; called by muse, mutect2, varscan2
- BRD2 | c.642G>C p.Q214H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100875596; called by muse, mutect2, varscan2
- BRWD3 | c.3009G>C p.L1003F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100955808; called by muse, mutect2, varscan2
- BTNL2 | c.1191G>C p.M397I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV100896015, COSV66631462; called by muse, mutect2
- BTNL2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs369335767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1GALT1C1 | c.269G>T p.W90L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100485589; called by muse, mutect2, varscan2
- CACNB2 | c.1124C>T p.A375V (on ENST00000324631 / NM_201596.3; = p.A320V on NM_000724.4) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs578106427, COSV56622691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN13 | c.1090G>C p.G364R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.246); catalogued as COSV99699947, COSV99700186; called by muse, mutect2, varscan2
- CARMIL3 | c.2707G>C p.D903H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100549419; called by muse, mutect2, varscan2
- CASKIN2 | c.2314C>A p.P772T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100050212; called by muse, mutect2
- CBX2 | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99490791; called by muse, mutect2, varscan2
- CCDC171 | c.2638A>G p.M880V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs751582263, COSV99900083; called by muse, mutect2, varscan2
- CCDC180 | c.3708G>C p.Q1236H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.824); catalogued as COSV63831735; called by muse, mutect2, varscan2
- CD101 | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV99869289; called by muse, mutect2, varscan2
- CD180 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as COSV99842149; called by muse, mutect2
- CDC25A | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.755); catalogued as COSV56772064; called by muse, mutect2, varscan2
- CFL1 | c.336G>C p.K112N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV100353999, COSV57378441; called by muse, mutect2, varscan2
- CHD7 | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101418077; called by muse, mutect2, varscan2
- CHGB | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66759868; called by muse, mutect2, varscan2
- CIBAR1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV100844640; called by muse, mutect2, varscan2
- CNKSR2 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101069889; called by muse, mutect2, varscan2
- COL2A1 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100475856, COSV61529027; called by muse, mutect2
- COL4A4 | c.3490C>A p.P1164T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.341); catalogued as COSV100306435; called by muse, mutect2, varscan2
- COMMD6 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV100869862; called by muse, mutect2, varscan2
- CSF1R | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs1256984931, COSV53834937; called by muse, mutect2, varscan2
- CSPP1 | c.3472C>G p.L1158V (on ENST00000676605; = p.L1117V on NM_024790.6) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV99138141; called by muse, mutect2, varscan2
- CSTF2 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100802926; called by muse, mutect2, varscan2
- DENND6A | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100231358; called by muse, mutect2, varscan2
- DHX30 | c.3277C>T p.Q1093* (on ENST00000445061 / NM_138615.3; = p.Q1054* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99050070; called by muse, mutect2, varscan2
- DICER1 | c.2639C>T p.P880L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1456764595, COSV100601883; called by muse, mutect2, varscan2
- DLAT | c.1577T>G p.V526G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99734524; called by muse, mutect2, varscan2
- DNAH8 | c.3755C>T p.S1252L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs776999715, COSV100543936; called by muse, mutect2, varscan2
- DST | c.13762G>C p.D4588H (on ENST00000361203 / NM_001374722.1; = p.D2176H on NM_015548.5) | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99752801; called by muse, mutect2
- DVL2 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99138390; called by muse, mutect2, varscan2
- EPG5 | c.1498-1G>A p.X500_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99956755; called by muse, mutect2
- EPHB3 | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs928574732, COSV100382882; called by muse, mutect2
- ERBB2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1293998208, COSV99507111; called by muse, mutect2, varscan2
- FAM114A2 | c.1318A>G p.T440A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100697615; called by muse, mutect2, varscan2
- FLT3 | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99607880; called by muse, mutect2, varscan2
- FOXA3 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 20/615 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV100141185, COSV100141279; called by muse, mutect2
- FZD6 | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.307); catalogued as COSV100708330; called by muse, mutect2, varscan2
- FZR1 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100553446, COSV58051583; called by muse, mutect2, varscan2
- GBP6 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs142400726; called by muse, mutect2, varscan2
- GDAP1 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99619425; called by muse, mutect2, varscan2
- GPC2 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99444442; called by muse, mutect2
- HEG1 | c.2039C>G p.S680C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100230234; called by muse, mutect2, varscan2
- HHIP | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV99666850; called by muse, mutect2, varscan2
- HNRNPA1 | c.1094G>C p.S365T (on ENST00000340913 / NM_031157.4; = p.S313T on NM_002136.4) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99267460; called by muse, mutect2, varscan2
- HOXC6 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV99678982; called by muse, mutect2
- HP1BP3 | c.1505C>A p.A502D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV100391630; called by muse, mutect2, varscan2
- HPS6 | c.2140G>C p.D714H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.971); catalogued as COSV100154816; called by muse, mutect2, varscan2
- HSD17B1 | c.530T>G p.F177C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs773613890, COSV56797050, COSV99864676; called by muse, mutect2, varscan2
- HSPB2 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.514); catalogued as COSV99909774; called by muse, mutect2
- HTRA2 | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99239530; called by muse, mutect2, varscan2
- IGF2BP1 | c.1571C>A p.P524Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51734216, COSV99288400; called by muse, mutect2, varscan2
- IGHV1-58 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as rs782274668; called by muse, mutect2
- IL36RN | c.303C>A p.Y101* | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | catalogued as COSV100697235; called by muse, mutect2
- INSYN1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs539347695, COSV65837098, COSV65837574; called by muse, mutect2, varscan2
- IQSEC2 | c.2890-1G>A p.X964_splice (on ENST00000642864 / NM_001111125.3; = p.X759_splice on NM_015075.2) | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100944781; called by muse, mutect2
- KALRN | c.8681G>A p.R2894K (on ENST00000360013 / NM_001024660.4; = p.R1197K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.39); catalogued as COSV52259727, COSV52260509; called by muse, mutect2, varscan2
- KCNJ3 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs369917007; called by muse, mutect2, varscan2
- KDM5B | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs748511684, COSV99350254; called by muse, mutect2, varscan2
- KIAA0100 | c.1628C>G p.S543C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV101197248; called by muse, mutect2, varscan2
- KIF5A | c.141T>A p.Y47* | Nonsense Mutation (SNP) | VAF 45/135 reads (33%) | catalogued as COSV99672633; called by muse, mutect2, varscan2
- KREMEN1 | c.787G>A p.D263N (on ENST00000407188; = p.D265N on NM_032045.5) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100588613; called by muse, mutect2, varscan2
- LAMA3 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100555854; called by muse, mutect2, varscan2
- LAMB4 | c.2905C>A p.P969T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99223283; called by muse, mutect2
- LGALS3BP | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs574745905, COSV99431447; called by muse, mutect2, varscan2
- LMOD2 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV101505426; called by muse, mutect2
- LRP2 | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99787135; called by muse, mutect2, varscan2
- LYST | c.9896A>G p.Y3299C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375053252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAGEE2 | c.232C>A p.R78S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.585); catalogued as COSV100973024, COSV64897824; called by muse, mutect2, varscan2
- MAP4K5 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.93); catalogued as COSV99184528; called by muse, mutect2, varscan2
- MGA | c.3667G>C p.E1223Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99579049; called by muse, mutect2, varscan2
- MPPED2 | c.786C>G p.D262E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100813145, COSV63895997; called by muse, mutect2, varscan2
- MUC16 | c.39148T>G p.L13050V | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.105); catalogued as rs750295511, COSV67441624; called by muse, mutect2, varscan2
- MYO9B | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.382); catalogued as COSV101261419; called by muse, mutect2, varscan2
- NAA50 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.277); catalogued as COSV99568533; called by muse, mutect2, varscan2
- NANOG | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV99981472; called by muse, varscan2
- NFAT5 | c.3394C>A p.P1132T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100590611; called by muse, mutect2, varscan2
- NME1 | c.209C>G p.S70* | Nonsense Mutation (SNP) | VAF 6/89 reads (7%) | catalogued as COSV99184011; called by muse, mutect2
- NOCT | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54936924; called by muse, mutect2
- OR11A1 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as rs747972434, COSV65820709; called by muse, mutect2, varscan2
- OR4A15 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as rs949520783, COSV100123916; called by muse, mutect2, varscan2
- PCSK2 | c.438G>C p.L146F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99359027; called by muse, mutect2, varscan2
- PHKA1 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.282); catalogued as COSV100262676; called by muse, mutect2
- PIK3AP1 | c.1718C>G p.S573* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100225599; called by muse, mutect2, varscan2
- PKHD1 | c.3298T>G p.F1100V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV100581871; called by muse, mutect2, varscan2
- PLCH1 | c.155G>A p.R52Q (on ENST00000340059 / NM_001130960.2; = p.R64Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs370205187; called by muse, mutect2, varscan2
- PLPP5 | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs757419576, COSV100395129; called by muse, mutect2
- PLSCR5 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101494476; called by muse, mutect2, varscan2
- POMT1 | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100586201; called by muse, mutect2, varscan2
- PPEF2 | c.1597A>G p.I533V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.185); catalogued as rs372081041; called by muse, mutect2, varscan2
- PRAG1 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV100421977; called by muse, mutect2, varscan2
- PSMG2 | c.337A>C p.S113R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV100466371; called by muse, mutect2, varscan2
- PTPRC | c.2403+1G>T p.X801_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100722275, COSV61421327; called by mutect2, varscan2
- RAB40A | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100420880; called by muse, mutect2, varscan2
- RARS2 | c.39T>C p.L13= | Splice Region (SNP) | VAF 5/49 reads (10%) | catalogued as COSV101057112, COSV65761633; called by muse, mutect2
- RASA3 | c.1108T>C p.F370L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100480105; called by muse, mutect2, varscan2
- RB1CC1 | c.3860T>C p.L1287S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99208920; called by muse, mutect2, varscan2
- REEP2 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99649535; called by muse, mutect2, varscan2
- REV3L | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100725028; called by muse, mutect2
- ROBO2 | c.2162G>C p.G721A | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165056, COSV59894479; called by muse, mutect2, varscan2
- RPL24 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV67529827; called by muse, mutect2, varscan2
- RSF1 | c.2084C>G p.S695C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV100406977; called by muse, mutect2, varscan2
- SENP6 | c.1803G>C p.E601D | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs762574501, COSV100519048; called by muse, mutect2, varscan2
- SETD3 | c.1092-2A>T p.X364_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100074913; called by muse, mutect2, varscan2
- SETDB1 | c.3593G>A p.R1198H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54987178; called by muse, mutect2, varscan2
- SFTPD | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as COSV100954497; called by muse, mutect2, varscan2
- SHROOM2 | c.3844C>T p.Q1282* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV101098321; called by muse, mutect2, varscan2
- SLC35A1 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101060066; called by muse, mutect2, varscan2
- SLC40A1 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV53723414, COSV99656185; called by muse, mutect2, varscan2
- SLCO1A2 | c.1490T>C p.L497P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV100261472; called by muse, mutect2, varscan2
- SORCS3 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.05); catalogued as COSV100864794; called by muse, mutect2, varscan2
- ST18 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 29/161 reads (18%) | catalogued as COSV99388788; called by muse, mutect2, varscan2
- SULT1A2 | c.837C>G p.D279E | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as rs762427733, COSV100187071; called by muse, mutect2, varscan2
- SWT1 | c.2537A>T p.Q846L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV100833140; called by muse, mutect2, varscan2
- SYAP1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs779127204, COSV101204919; called by muse, varscan2
- TAOK1 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99913701; called by muse, mutect2
- TGFB2 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV100859938; called by muse, mutect2, varscan2
- TMEM259 | c.1239C>G p.F413L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV99312290; called by muse, mutect2
- TMEM98 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.266); catalogued as COSV99912809; called by muse, mutect2, varscan2
- TRMT1L | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV100834585; called by muse, mutect2, varscan2
- TTC23L | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs745472103, COSV101551109; called by muse, mutect2, varscan2
- TTN | c.77195C>T p.P25732L (on ENST00000591111; = p.P18308L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | PolyPhen probably damaging (0.999); catalogued as COSV100600633; called by muse, mutect2, varscan2
- TTN | c.39440C>G p.S13147C (on ENST00000591111; = p.S5723C on NM_003319.4) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | PolyPhen probably damaging (0.98); catalogued as COSV100600635; called by muse, mutect2, varscan2
- TXNDC16 | c.63C>A p.Y21* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99908979; called by muse, mutect2, varscan2
- TXNDC2 | c.1537G>T p.V513L (on ENST00000306084 / NM_001098529.2; = p.V446L on NM_032243.6) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100045885; called by muse, mutect2, varscan2
- UGGT2 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100942497; called by muse, mutect2, varscan2
- UGT2B4 | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 28/316 reads (9%) | catalogued as COSV59321232; called by muse, mutect2
- USP30 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs139314514; called by mutect2, varscan2
- WDR17 | c.2780G>A p.G927E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54575087, COSV99707095; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1780C>G p.Q594E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.82); catalogued as COSV58742186; called by muse, mutect2, varscan2
- ZNF461 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100831373; called by muse, mutect2, varscan2
- CYP4F22 | c.1431_1441del p.Q478Hfs*98 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- KIF14 | c.2542del p.D848Ifs*12 | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | called by mutect2, pindel, varscan2
- MVK | c.813_818del p.I271_L273delinsM | In Frame Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- STIL | c.2947dup p.T983Nfs*14 | Frame Shift Ins (INS) | VAF 37/135 reads (27%) | called by mutect2, varscan2
- TAF15 | c.914G>C p.G305A (on ENST00000605844 / NM_139215.3; = p.G302A on NM_003487.4) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ADAM21 | c.1674C>G p.V558= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV99960586; called by muse, mutect2
- AHNAK | c.9744G>A p.L3248= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99946291; called by muse, mutect2
- BPTF | c.5718G>C p.V1906= | Silent (SNP) | VAF 4/81 reads (5%) | catalogued as COSV100074389; called by muse, mutect2
- C7orf31 | c.486C>T p.T162= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99383810; called by muse, mutect2, varscan2
- CD248 | c.1149G>A p.K383= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1395758118, COSV100256520; called by muse, mutect2
- CEP72 | c.891C>T p.F297= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs147233719; called by muse, mutect2, varscan2
- CHD1L | c.537G>A p.L179= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100787387, COSV63615247; called by muse, mutect2, varscan2
- CLSTN1 | c.1410G>A p.V470= (on ENST00000377298 / NM_001009566.3; = p.V460= on NM_014944.4) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100790500; called by muse, mutect2, varscan2
- DCAF12L1 | c.411G>C p.R137= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as COSV100948155; called by muse, mutect2, varscan2
- DDX47 | c.660G>A p.L220= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV100774514; called by muse, mutect2, varscan2
- DGAT1 | c.618C>A p.L206= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100183965; called by muse, mutect2
- ECHS1 | c.744T>C p.F248= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100881881; called by mutect2, varscan2
- EPHB2 | c.264G>T p.V88= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101006837, COSV101007275; called by muse, mutect2, varscan2
- EZHIP | c.888G>A p.A296= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs553854387, COSV57955188; called by muse, mutect2, varscan2
- FBXL7 | c.579C>T p.V193= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100309347; called by muse, mutect2, varscan2
- FLT4 | c.2211C>T p.R737= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1297285649, COSV56122455; called by muse, mutect2
- GAS6 | c.1923C>T p.R641= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as rs760636776, COSV100581241; called by muse, mutect2, varscan2
- GPRIN2 | c.78C>T p.S26= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as COSV100966324; called by muse, mutect2
- H2BC8 | c.264G>A p.S88= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs765729377, COSV99773113; called by muse, mutect2, varscan2
- HEPH | c.2580T>C p.Y860= (on ENST00000343002; = p.Y593= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100294362; called by muse, mutect2
- HEPHL1 | c.813C>T p.L271= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100243680; called by muse, mutect2
- JPH4 | c.1755G>C p.L585= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100436613; called by muse, mutect2, varscan2
- KLHDC3 | c.624C>T p.N208= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99763612; called by muse, mutect2, varscan2
- LTC4S | c.39C>T p.L13= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV99482124; called by muse, mutect2
- MARCHF10 | c.1980C>T p.R660= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100247976; called by muse, varscan2
- MBTPS1 | c.2637C>T p.L879= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1279105150, COSV100597423; called by muse, mutect2, varscan2
- MYH2 | c.3678G>A p.E1226= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV99819583; called by muse, mutect2, varscan2
- MYO10 | c.2865G>T p.R955= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99944932; called by muse, mutect2
- NLGN4X | c.1893G>A p.K631= | Silent (SNP) | VAF 31/191 reads (16%) | catalogued as COSV99320528; called by muse, mutect2, varscan2
- OR4A5 | c.759C>T p.F253= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV60521402, COSV60521592; called by muse, mutect2, varscan2
- PELP1 | c.1284G>T p.R428= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99342640; called by muse, mutect2, varscan2
- PGBD5 | c.534C>T p.F178= (on ENST00000525115; = p.F247= on NM_001258311.2) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100358428; called by muse, mutect2
- PHF7 | c.528G>A p.Q176= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100015335; called by muse, mutect2, varscan2
- PLXNA3 | c.54G>A p.L18= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100859848; called by muse, mutect2, varscan2
- POLK | c.1026G>C p.V342= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99605685; called by muse, mutect2, varscan2
- PSMD10 | c.663G>A p.K221= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99480629; called by muse, mutect2, varscan2
- RTL8A | c.189G>A p.L63= | Silent (SNP) | VAF 10/143 reads (7%) | catalogued as COSV100887710; called by muse, mutect2
- SC5D | c.645C>A p.V215= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as COSV99873008; called by muse, mutect2, varscan2
- SFTA2 | c.90G>C p.L30= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100764470; called by muse, mutect2, varscan2
- SMC6 | c.1890C>G p.P630= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100704874; called by muse, mutect2
- SPAG5 | c.1155G>T p.G385= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs1434936514, COSV100410493; called by muse, mutect2
- TMEM67 | c.1864C>T p.L622= | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as rs749637489, COSV100018832; called by muse, mutect2, varscan2
- UBQLN2 | c.1767C>T p.L589= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100592650; called by muse, mutect2, varscan2
- ZDHHC18 | c.1062G>C p.R354= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100938816; called by muse, mutect2, varscan2
- AC024940.1 | n.4733G>C | RNA (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3060G>T | RNA (SNP) | VAF 66/359 reads (18%) | catalogued as rs372747972; called by muse, mutect2, varscan2
- ATAT1 | c.107+213T>C | Intron (SNP) | VAF 14/63 reads (22%) | catalogued as COSV99457612; called by muse, mutect2, varscan2
- BLVRB | c.-1G>A | 5'UTR (SNP) | VAF 29/160 reads (18%) | catalogued as rs1476245235, COSV99647869, COSV99648075; called by muse, mutect2, varscan2
- CADM2 | c.62-75516C>T | Intron (SNP) | VAF 9/58 reads (16%) | catalogued as COSV67375995; called by muse, mutect2, varscan2
- ZNF436 | c.-68G>A | 5'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100010950; called by muse, mutect2, varscan2
